Somatic mutation profile of tumor specimen ALCH-B26G-TTP1-A (aliquot ALCH-B26G-TTP1-A-1-0-D-A774-36) from ALCHEMIST case ALCH-B26G, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 80.2 years (29,310 days).
Specimen ALCH-B26G-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4dd5e4a-4559-4f2d-87b6-d6952bcc9f02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B26G-NB1-A (Blood Derived Normal), aliquot ALCH-B26G-NB1-A-1-0-D-A774-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07924ce3-bf71-4015-b9da-a4dc048dc53d

The open-access MAF lists 59 somatic variants for this specimen: 38 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 17, Nonsense Mutation 4, Frame Shift Del 4, Intron 3, 3'UTR 1, Splice Site 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FANCA | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 62/245 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as rs769479800, CM050593, CM145989; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 174/385 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 30/92 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 13/384 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, mutect2
- ARSL | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 100/322 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs778253985, CM109461; called by muse, mutect2, varscan2
- BTBD16 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs769336919, COSV99584985; called by muse, mutect2, varscan2
- COL4A6 | c.1034G>A p.G345D | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57866308; called by muse, varscan2
- GABRA3 | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 55/170 reads (32%) | catalogued as rs754301642, COSV64795089; called by muse, mutect2, varscan2
- GPR19 | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs377366501; called by muse, mutect2
- HS3ST4 | c.1010C>A p.A337E | Missense Mutation (SNP) | VAF 84/301 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100499951; called by muse, mutect2, varscan2
- KRTAP10-7 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs376631519; called by muse, varscan2
- MS4A3 | c.479C>G p.P160R | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.737); catalogued as COSV53936236, COSV99614871; called by muse, mutect2, varscan2
- PHYKPL | c.1180_1182del p.E394del | In Frame Del (DEL) | VAF 33/109 reads (30%) | catalogued as rs749456568; called by mutect2, pindel
- PLEKHG4B | c.1394C>T p.A465V (on ENST00000283426; = p.A821V on NM_052909.5) | Missense Mutation (SNP) | VAF 122/429 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.36); catalogued as rs376874976; called by muse, mutect2, varscan2
- PNISR | c.647del p.P216Lfs*2 | Frame Shift Del (DEL) | VAF 114/401 reads (28%) | catalogued as COSV65079252; called by mutect2, pindel, varscan2
- PRAMEF12 | c.1081G>A p.V361M | Missense Mutation (SNP) | VAF 111/333 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs200049428; called by muse, mutect2, varscan2
- SLC25A43 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 74/216 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); catalogued as rs775379926; called by muse, mutect2, varscan2
- SMOC2 | c.955G>A p.A319T (on ENST00000356284 / NM_001166412.2; = p.A330T on NM_022138.3) | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs921951281; called by muse, mutect2, varscan2
- SSTR4 | c.1016C>A p.A339D | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.211); catalogued as COSV54799102; called by muse, mutect2, varscan2
- SUPT20H | c.2233A>G p.M745V (on ENST00000350612 / NM_001014286.3; = p.Y711C on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377592079; called by muse, mutect2, varscan2
- ZNF248 | c.613C>A p.L205I | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.946); catalogued as rs778822219; called by muse, mutect2, varscan2
- ABCA12 | c.5365C>T p.Q1789* (on ENST00000272895 / NM_173076.3; = p.Q1471* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 80/352 reads (23%) | called by muse, mutect2, varscan2
- ABCF3 | c.331_332del p.K111Efs*20 | Frame Shift Del (DEL) | VAF 90/407 reads (22%) | called by mutect2, pindel, varscan2
- CELSR2 | c.1147G>C p.A383P | Missense Mutation (SNP) | VAF 99/336 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL4A2 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 62/212 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- DUSP13 | c.499C>G p.P167A | Missense Mutation (SNP) | VAF 16/451 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2
- FAM221B | c.542del p.K181Rfs*3 | Frame Shift Del (DEL) | VAF 11/102 reads (11%) | called by mutect2, pindel, varscan2
- MAGEB10 | c.445T>A p.F149I | Missense Mutation (SNP) | VAF 97/243 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MGARP | c.187-1G>A p.X63_splice | Splice Site (SNP) | VAF 7/116 reads (6%) | called by muse, mutect2
- MSI2 | c.507G>T p.E169D | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- NUP210L | c.3181G>A p.V1061M | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- PRAMEF19 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RAD51 | c.443T>C p.I148T | Missense Mutation (SNP) | VAF 102/400 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- REPIN1 | c.233_243del p.R78Pfs*8 | Frame Shift Del (DEL) | VAF 97/333 reads (29%) | called by mutect2, pindel, varscan2
- SURF6 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- UBQLN3 | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- ZEB2 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 96/465 reads (21%) | called by muse, mutect2, varscan2
- ZNF280C | c.1077C>A p.Y359* | Nonsense Mutation (SNP) | VAF 79/240 reads (33%) | called by muse, mutect2, varscan2
- AFF2 | c.288A>G p.G96= | Silent (SNP) | VAF 26/239 reads (11%) | called by muse, mutect2
- C8orf37 | c.462G>A p.L154= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as rs1563470694; called by muse, mutect2, varscan2
- CEACAM18 | c.798C>T p.H266= | Silent (SNP) | VAF 96/368 reads (26%) | called by muse, mutect2, varscan2
- CREB3L3 | c.312C>T p.S104= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs537344264; called by muse, mutect2, varscan2
- EXT1 | c.612C>A p.T204= | Silent (SNP) | VAF 162/565 reads (29%) | catalogued as CX099383, COSV65474806, COSV65486521; called by muse, mutect2, varscan2
- HERC2 | c.11598C>T p.A3866= | Silent (SNP) | VAF 58/212 reads (27%) | catalogued as rs368888287; called by muse, mutect2, varscan2
- IL34 | c.114G>T p.T38= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as COSV55380037; called by muse, mutect2, varscan2
- MEMO1 | c.780G>A p.Q260= | Silent (SNP) | VAF 44/110 reads (40%) | called by muse, mutect2, varscan2
- OR5AC2 | c.429C>T p.S143= | Silent (SNP) | VAF 42/125 reads (34%) | catalogued as rs766551661, COSV62279923; called by muse, mutect2, varscan2
- PRKCE | c.489G>A p.R163= | Silent (SNP) | VAF 165/377 reads (44%) | called by muse, mutect2, varscan2
- SLC25A22 | c.48C>A p.G16= | Silent (SNP) | VAF 76/476 reads (16%) | catalogued as COSV57193544; called by muse, mutect2, varscan2
- SLC39A4 | c.1023G>A p.A341= (on ENST00000301305 / NM_001374839.1; = p.A316= on NM_017767.3) | Silent (SNP) | VAF 46/183 reads (25%) | catalogued as rs572767840; called by muse, mutect2, varscan2
- SLC6A15 | c.174A>G p.E58= | Silent (SNP) | VAF 94/317 reads (30%) | called by muse, mutect2, varscan2
- SRRM5 | c.666G>A p.P222= | Silent (SNP) | VAF 57/180 reads (32%) | catalogued as rs889671804; called by muse, mutect2, varscan2
- TAB1 | c.1269T>C p.S423= | Silent (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- TMF1 | c.1434T>A p.A478= | Silent (SNP) | VAF 31/84 reads (37%) | called by muse, mutect2, varscan2
- ZNF98 | c.735A>G p.K245= | Silent (SNP) | VAF 40/220 reads (18%) | called by muse, mutect2
- AC107023.1 | n.25+11399G>T | Intron (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- AC109583.1 | c.-1319+369A>G | Intron (SNP) | VAF 49/151 reads (32%) | catalogued as rs1434047607; called by muse, mutect2, varscan2
- FN1 | c.*28dup | 3'UTR (INS) | VAF 156/425 reads (37%) | called by pindel, varscan2
- ZNF638 | c.2378-874G>A | Intron (SNP) | VAF 89/258 reads (34%) | called by muse, mutect2, varscan2
